Somatic mutation profile of cancer-model specimen HCM-CSHL-0380-C18-85A (3D Organoid; aliquot HCM-CSHL-0380-C18-85A-01D-A79C-36), derived from the primary tumor of HCMI case HCM-CSHL-0380-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 69.1 years (25,249 days).
Specimen HCM-CSHL-0380-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6b4d5e8-e8ef-4659-8c7f-485ba354e9d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0380-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0380-C18-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7ba8366-1c6a-47af-82a2-f299acf3b420

The open-access MAF lists 1,607 somatic variants for this specimen: 1,115 protein-altering or splice-affecting, 412 silent, 80 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 778, Silent 412, Frame Shift Del 223, Frame Shift Ins 47, Intron 43, Nonsense Mutation 41, 3'UTR 14, In Frame Del 9, Splice Region 9, 5'Flank 9, Splice Site 6, 5'UTR 6.

Variants (750 of 1,607; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8432del p.K2811Sfs*46 | Frame Shift Del (DEL) | VAF 23/141 reads (16%) | catalogued as rs587782558; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- BMPR1A | c.176del p.L59* | Frame Shift Del (DEL) | VAF 122/322 reads (38%) | catalogued as rs786201038; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/174 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL5A1 | c.2897del p.P966Lfs*108 | Frame Shift Del (DEL) | VAF 140/387 reads (36%) | catalogued as rs1179967153; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 82/433 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, varscan2
- CTNNB1 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 90/432 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic /  other / pathogenic; called by muse, varscan2
- ERI1 | c.627del p.V210* | Frame Shift Del (DEL) | VAF 89/225 reads (40%) | catalogued as rs1563322318; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- HK1 | c.1334C>T p.S445L | Missense Mutation (SNP) | VAF 289/501 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064794848; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.687del p.A230Lfs*16 | Frame Shift Del (DEL) | VAF 108/264 reads (41%) | catalogued as rs63749897; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 92/171 reads (54%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NAGLU | c.648del p.S217Pfs*22 | Frame Shift Del (DEL) | VAF 216/553 reads (39%) | catalogued as rs760370189; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NPHS1 | c.2479C>T p.R827* | Nonsense Mutation (SNP) | VAF 230/503 reads (46%) | catalogued as rs140018064, CM044915; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLG | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 78/434 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780953863, CM021661, CM068612, COSV51523661; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 196/465 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 342/550 reads (62%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.93); catalogued as rs375671514, COSV55297373; ClinVar: uncertain significance; called by muse, mutect2
- AANAT | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 348/717 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs770524125, COSV51686543; called by muse, mutect2, varscan2
- ABCA13 | c.14479G>A p.G4827R | Missense Mutation (SNP) | VAF 110/219 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560141424, COSV68944665, COSV68951015; called by muse, mutect2, varscan2
- ABCA3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 140/311 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs746902527, COSV57052156; called by muse, mutect2, varscan2
- ABCA4 | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as rs547063913, COSV64671258; called by muse, mutect2, varscan2
- ABCB10 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 185/370 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV100747942; called by muse, mutect2, varscan2
- ABCB10 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 188/395 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as rs138468815; called by muse, mutect2, varscan2
- ABCC1 | c.1814G>A p.S605N | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.049); catalogued as rs747209855; called by muse, mutect2
- ABCC1 | c.4040C>T p.A1347V | Missense Mutation (SNP) | VAF 79/440 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.768); catalogued as COSV60690532, COSV60692854; called by muse, varscan2
- ABI3BP | c.1779C>A p.S593R | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.795); catalogued as rs756163529; called by muse, varscan2
- ABTB1 | c.544G>A p.V182I (on ENST00000232744 / NM_172027.3; = p.V40I on NM_032548.3) | Missense Mutation (SNP) | VAF 104/284 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs779240937; called by muse, mutect2, varscan2
- ABTB2 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 53/378 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs773899230, COSV54386083; called by muse, varscan2
- ACAP3 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 199/427 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757717274, COSV61222058; called by muse, mutect2, varscan2
- ACOT1 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 280/778 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs375253960, COSV58570851; called by muse, varscan2
- ACTL7B | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 249/556 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1301600694, COSV65926925; called by muse, mutect2, varscan2
- ACTRT1 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 249/249 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs185459023, COSV100947479; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 234/244 reads (96%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS18 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 190/387 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs1428931357, COSV51400901, COSV51419834; called by muse, varscan2
- ADAP2 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 193/375 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261551676; called by muse, mutect2, varscan2
- ADARB2 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 346/699 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1322029552, COSV67228331; called by muse, mutect2, varscan2
- ADCY9 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 182/421 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as rs374631917; called by muse, mutect2, varscan2
- ADGRB1 | c.1687del p.Q563Rfs*27 | Frame Shift Del (DEL) | VAF 185/416 reads (44%) | catalogued as COSV60094001; called by mutect2, varscan2
- ADGRL3 | c.2501C>T p.T834M (on ENST00000506720 / NM_001322402.2; = p.T766M on NM_015236.6) | Missense Mutation (SNP) | VAF 168/363 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.75); catalogued as rs376555701, COSV101547454, COSV99072522; called by muse, mutect2, varscan2
- ADGRV1 | c.3058G>A p.A1020T | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV104434953; called by muse, mutect2, varscan2
- ADNP | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 196/413 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1568710507, COSV62426617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADRB3 | c.956del p.G319Afs*4 | Frame Shift Del (DEL) | VAF 238/620 reads (38%) | catalogued as rs1563397465; called by mutect2, pindel, varscan2
- AEBP1 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368135596; called by muse, mutect2, varscan2
- AFDN | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs779923554, COSV99053078; called by muse, mutect2, varscan2
- AGPAT3 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 209/400 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs200808478, COSV52371469; called by muse, mutect2, varscan2
- AHNAK | c.92G>A p.G31D | Missense Mutation (SNP) | VAF 262/553 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1276199931, COSV57222700; called by muse, mutect2, varscan2
- AHNAK2 | c.14198C>T p.T4733M | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.265); catalogued as rs373884407; called by muse, mutect2, varscan2
- AICDA | c.145C>T p.L49F | Missense Mutation (SNP) | VAF 110/362 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57564058, COSV99984100; called by muse, mutect2, varscan2
- AK4 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.557); catalogued as rs778627421, COSV59196670; called by muse, mutect2, varscan2
- AKAP10 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 199/371 reads (54%) | SIFT tolerated (0.26); PolyPhen benign (0.112); catalogued as rs778031140; called by muse, mutect2, varscan2
- AKAP12 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.374); catalogued as rs568033766, COSV53579189; called by muse, mutect2
- AMBRA1 | c.1783G>T p.E595* (on ENST00000458649 / NM_001367468.1; = p.E505* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 452/452 reads (100%) | catalogued as COSV54047898, COSV54062127; called by muse, mutect2, varscan2
- ANGPTL7 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 233/465 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs924321890, COSV63869151; called by muse, mutect2, varscan2
- ANKMY1 | c.1048C>T p.R350W | Missense Mutation (SNP) | VAF 177/387 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs144393814; called by muse, mutect2, varscan2
- ANKRD17 | c.7532C>T p.S2511F | Missense Mutation (SNP) | VAF 114/248 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.854); catalogued as COSV58230141; called by muse, mutect2, varscan2
- AOC2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 241/515 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs145007333; called by muse, mutect2, varscan2
- AP1M2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 66/148 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs772650211, COSV51566779; called by muse, mutect2, varscan2
- ARHGEF26 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 162/334 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV62847241; called by muse, mutect2, varscan2
- ARHGEF28 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 138/286 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs112237001, COSV99709960; called by muse, mutect2, varscan2
- ARHGEF33 | c.10del p.T4Pfs*13 | Frame Shift Del (DEL) | VAF 80/234 reads (34%) | catalogued as rs781444055; called by mutect2, pindel, varscan2
- ARHGEF40 | c.4145G>A p.R1382Q | Missense Mutation (SNP) | VAF 150/283 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs527700988; called by muse, mutect2, varscan2
- ARHGEF7 | c.67del p.T23Pfs*13 | Frame Shift Del (DEL) | VAF 218/415 reads (53%) | catalogued as rs754827718; called by mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 274/644 reads (43%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ASB10 | c.614C>T p.A205V (on ENST00000420175 / NM_001142459.2; = p.A190V on NM_080871.4) | Missense Mutation (SNP) | VAF 160/375 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375044701, COSV51999898; called by muse, mutect2, varscan2
- ASCC3 | c.489dup p.G164Wfs*2 | Frame Shift Ins (INS) | VAF 72/202 reads (36%) | catalogued as rs747570359; called by mutect2, varscan2
- ASCL4 | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 386/1225 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs761289333, COSV60817002; called by muse, mutect2, varscan2
- ASIC3 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 335/666 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs150462572; called by muse, mutect2, varscan2
- ASMT | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 258/523 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs780967376, COSV101172395; called by muse, mutect2, varscan2
- ATIC | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 93/217 reads (43%) | catalogued as rs1025725483, COSV52694765; called by muse, mutect2, varscan2
- ATP13A5 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs1424370848, COSV100664667; called by muse, mutect2
- ATP6V1H | c.1034G>A p.S345N | Missense Mutation (SNP) | VAF 90/161 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.414); catalogued as rs1475735797, COSV100778741; called by muse, mutect2, varscan2
- ATPAF1 | c.305G>A p.R102H (on ENST00000574428; = p.R125H on NM_022745.4) | Missense Mutation (SNP) | VAF 154/375 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); catalogued as rs766445923, COSV61305019; called by muse, mutect2, varscan2
- ATRN | c.3977G>A p.R1326H | Missense Mutation (SNP) | VAF 161/339 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1190021385; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 189/418 reads (45%) | catalogued as rs1288664341; called by mutect2, varscan2
- AXIN2 | c.2062del p.L688* | Frame Shift Del (DEL) | VAF 71/833 reads (9%) | catalogued as CM067349, COSV61056020; called by mutect2, pindel
- B3GNTL1 | c.342G>A p.S114= | Splice Region (SNP) | VAF 22/135 reads (16%) | catalogued as rs576245927; called by muse, mutect2, varscan2
- B4GALNT4 | c.1458del p.T487Pfs*8 | Frame Shift Del (DEL) | VAF 247/590 reads (42%) | catalogued as rs1381079472; called by mutect2, pindel, varscan2
- B4GALT3 | c.840del p.T281Hfs*3 | Frame Shift Del (DEL) | VAF 201/487 reads (41%) | catalogued as COSV100158016; called by mutect2, pindel, varscan2
- BACH2 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 240/514 reads (47%) | catalogued as COSV57612930; called by muse, mutect2, varscan2
- BAG3 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 257/499 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556000090, COSV100958264, COSV100958273; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BBOF1 | c.405del p.A136Pfs*6 | Frame Shift Del (DEL) | VAF 167/355 reads (47%) | catalogued as rs1456367734; called by mutect2, pindel, varscan2
- BCORL1 | c.3227A>G p.Q1076R | Missense Mutation (SNP) | VAF 315/315 reads (100%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.017); catalogued as rs1170303027; called by muse, mutect2, varscan2
- BNIP5 | c.1702dup p.Y568Lfs*24 | Frame Shift Ins (INS) | VAF 132/309 reads (43%) | catalogued as rs747868798; called by mutect2, varscan2
- BOP1 | c.106del p.L36Sfs*154 | Frame Shift Del (DEL) | VAF 45/321 reads (14%) | catalogued as rs782133829; called by mutect2, pindel, varscan2
- BRD3 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 240/484 reads (50%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.97); catalogued as rs62639321, COSV100324812; called by muse, mutect2, varscan2
- BRINP3 | c.1192A>T p.T398S | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66530788; called by muse, mutect2, varscan2
- BSG | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 386/838 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776570652; called by muse, mutect2, varscan2
- BSN | c.4799C>T p.P1600L | Missense Mutation (SNP) | VAF 228/507 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs200564136; called by muse, mutect2, varscan2
- BTBD17 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 269/563 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64729301; called by muse, varscan2
- BTN3A2 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 128/208 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749453475; called by muse, mutect2, varscan2
- BUB1 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 162/329 reads (49%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs200797921; called by muse, mutect2, varscan2
- C10orf88 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 150/817 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767472713; called by muse, mutect2, varscan2
- C17orf113 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 434/804 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs541264806; called by muse, mutect2, varscan2
- C20orf204 | c.366_367del p.R122Sfs*? | Frame Shift Del (DEL) | VAF 352/890 reads (40%) | catalogued as rs1473664174; called by pindel, varscan2
- C2orf50 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 298/648 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1193767583; called by muse, varscan2
- C4orf17 | c.253del p.S85Pfs*10 | Frame Shift Del (DEL) | VAF 187/466 reads (40%) | catalogued as rs201447915; called by mutect2, pindel, varscan2
- C7 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 100/248 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775095625, COSV57472920; called by muse, mutect2, varscan2
- CACNA1D | c.1456C>T p.R486* | Nonsense Mutation (SNP) | VAF 138/298 reads (46%) | catalogued as rs372337098; called by muse, mutect2, varscan2
- CAMK1G | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 104/244 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs375301374; called by muse, mutect2, varscan2
- CARD10 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 250/514 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs367893893; called by muse, varscan2
- CASP1 | c.614del p.N205Ifs*7 (on ENST00000436863 / NM_033292.4; = p.N184Ifs*7 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 49/250 reads (20%) | catalogued as rs746543598, COSV62056860; called by mutect2, varscan2
- CBLL1 | c.419del p.K140Rfs*52 | Frame Shift Del (DEL) | VAF 79/184 reads (43%) | catalogued as rs1256378164; called by mutect2, pindel, varscan2
- CBX6 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 369/795 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1011003104; called by muse, mutect2, varscan2
- CBY2 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 189/385 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs759482874, COSV60119002; called by muse, mutect2, varscan2
- CC2D1A | c.2570G>A p.R857H | Missense Mutation (SNP) | VAF 173/351 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs772528161, COSV54308412; called by muse, mutect2, varscan2
- CCDC34 | c.731del p.N244Mfs*28 | Frame Shift Del (DEL) | VAF 76/182 reads (42%) | catalogued as rs773019149; called by mutect2, varscan2
- CCDC51 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 122/262 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs373332386; called by muse, mutect2, varscan2
- CCDC96 | c.55del p.E19Kfs*55 | Frame Shift Del (DEL) | VAF 252/738 reads (34%) | catalogued as rs1381480112; called by pindel, varscan2
- CCR10 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 436/882 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs748303358, COSV52854248; called by muse, mutect2, varscan2
- CCR7 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 134/280 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs776754449; called by muse, mutect2, varscan2
- CD164L2 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 51/432 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64996034; called by muse, mutect2, varscan2
- CDC16 | c.1295T>A p.I432N | Missense Mutation (SNP) | VAF 82/165 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52959926, COSV52961913; called by muse, mutect2, varscan2
- CDH1 | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 150/277 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV55733685; called by muse, mutect2, varscan2
- CDH22 | c.967G>A p.G323S | Missense Mutation (SNP) | VAF 233/483 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as rs369990920; called by muse, mutect2, varscan2
- CDH23 | c.4946C>T p.T1649M | Missense Mutation (SNP) | VAF 225/471 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs752362029, COSV56466603; called by muse, mutect2, varscan2
- CDR2L | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 308/607 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs761841230; called by muse, mutect2, varscan2
- CEMIP2 | c.2594C>T p.T865M | Missense Mutation (SNP) | VAF 99/194 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs934630238; called by muse, mutect2, varscan2
- CEP128 | c.3254C>A p.S1085* | Nonsense Mutation (SNP) | VAF 69/189 reads (37%) | catalogued as COSV55390244; called by muse, mutect2, varscan2
- CEP350 | c.6232del p.R2078Gfs*6 | Frame Shift Del (DEL) | VAF 154/360 reads (43%) | catalogued as rs759430139; called by mutect2, pindel, varscan2
- CEP350 | c.8183del p.N2728Tfs*7 | Frame Shift Del (DEL) | VAF 147/394 reads (37%) | catalogued as rs780253350; called by mutect2, pindel, varscan2
- CHD1L | c.761T>C p.L254S | Missense Mutation (SNP) | VAF 142/275 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs587612852; called by muse, mutect2, varscan2
- CHL1 | c.1519G>A p.A507T (on ENST00000397491 / NM_001253387.1; = p.A523T on NM_006614.4) | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as COSV56604520; called by muse, mutect2
- CHST4 | c.19del p.M7* | Frame Shift Del (DEL) | VAF 150/334 reads (45%) | catalogued as rs745406065; called by mutect2, pindel, varscan2
- CIITA | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 274/565 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as rs200354120; ClinVar: uncertain significance; called by muse, mutect2
- CILP2 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 380/778 reads (49%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.75); catalogued as COSV99364318; called by muse, varscan2
- CMTR1 | c.1700T>C p.I567T | Missense Mutation (SNP) | VAF 131/252 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1388279980; called by muse, mutect2, varscan2
- CMTR1 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 130/267 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1360436719, COSV65092011; called by muse, mutect2, varscan2
- COL16A1 | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 38/444 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs1269145053; called by muse, mutect2
- COL25A1 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 363/731 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV67659420; called by muse, mutect2, varscan2
- COL7A1 | c.5395G>T p.A1799S | Missense Mutation (SNP) | VAF 196/372 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV100098394; called by muse, varscan2
- COL8A1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 152/304 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); catalogued as rs769320857, COSV53732499, COSV53740065; called by muse, varscan2
- COL9A2 | c.595G>A p.G199R | Missense Mutation (SNP) | VAF 218/459 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1557801781; called by muse, mutect2, varscan2
- CPED1 | c.2778dup p.H927Tfs*4 | Frame Shift Ins (INS) | VAF 91/206 reads (44%) | catalogued as rs777945397; called by mutect2, varscan2
- CPSF1 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 259/558 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs781864837, COSV58234016; called by muse, mutect2, varscan2
- CPTP | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 205/425 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV100028504; called by muse, varscan2
- CPVL | c.1090G>A p.V364I | Missense Mutation (SNP) | VAF 128/210 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs778420273; called by muse, varscan2
- CR1L | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 246/538 reads (46%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.037); catalogued as COSV65469510; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 95/249 reads (38%) | catalogued as rs747832403; called by mutect2, pindel, varscan2
- CRAMP1 | c.2887G>T p.G963C | Missense Mutation (SNP) | VAF 174/338 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs570491301; called by muse, mutect2, varscan2
- CRAT | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 277/573 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs200481540, COSV58875900; called by muse, mutect2, varscan2
- CRB1 | c.2291G>A p.R764H | Missense Mutation (SNP) | VAF 52/458 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.708); catalogued as rs375040930, CM130791; ClinVar: uncertain significance; called by muse, mutect2
- CREB3L4 | c.718_720del p.E240del | In Frame Del (DEL) | VAF 107/238 reads (45%) | catalogued as rs771050350; called by mutect2, pindel, varscan2
- CRELD1 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 187/439 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs140474390; called by muse, mutect2, varscan2
- CRYBG2 | c.4451G>A p.G1484D | Missense Mutation (SNP) | VAF 129/278 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770836869; called by muse, mutect2, varscan2
- CUL2 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1303633670; called by muse, mutect2, varscan2
- CYP2S1 | c.1112T>C p.I371T | Missense Mutation (SNP) | VAF 28/622 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV59505367; called by muse, mutect2
- CYP7B1 | c.903G>A p.M301I | Missense Mutation (SNP) | VAF 187/358 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.14); catalogued as rs769758869; called by muse, mutect2, varscan2
- DACT3 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 148/249 reads (59%) | SIFT tolerated (0.62); PolyPhen benign (0.202); catalogued as rs1322243977; called by muse, mutect2, varscan2
- DBH | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 191/355 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV55042460; called by muse, mutect2, varscan2
- DCHS1 | c.3525C>A p.S1175R | Missense Mutation (SNP) | VAF 218/425 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.301); catalogued as rs1015111395; called by muse, mutect2, varscan2
- DCLK2 | c.2239del p.H747Tfs*153 | Frame Shift Del (DEL) | VAF 149/293 reads (51%) | catalogued as rs751255369; called by mutect2, pindel, varscan2
- DEFB128 | c.177G>T p.E59D | Missense Mutation (SNP) | VAF 172/373 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV57685589; called by muse, mutect2, varscan2
- DEFB129 | c.333del p.F111Lfs*15 | Frame Shift Del (DEL) | VAF 160/411 reads (39%) | catalogued as rs765896284; called by mutect2, pindel, varscan2
- DENND5B | c.2364A>G p.I788M | Missense Mutation (SNP) | VAF 373/568 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs539737071; called by muse, mutect2, varscan2
- DGKG | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 199/413 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53961780; called by muse, mutect2, varscan2
- DIAPH1 | c.3186G>A p.M1062I | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53878339; called by muse, varscan2
- DISP3 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 230/486 reads (47%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs554804846, COSV53836566; called by muse, mutect2, varscan2
- DLC1 | c.2285C>T p.T762I (on ENST00000276297 / NM_001348081.2; = p.T325I on NM_006094.5) | Missense Mutation (SNP) | VAF 267/496 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.391); catalogued as COSV99360308; called by muse, varscan2
- DLL1 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 328/682 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368185917, COSV64538279; called by muse, varscan2
- DNAH3 | c.10465C>T p.R3489W | Missense Mutation (SNP) | VAF 231/503 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs138099907; called by muse, mutect2, varscan2
- DNAH7 | c.10045C>T p.R3349C | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs367980316; called by muse, mutect2, varscan2
- DNAH9 | c.4018G>A p.A1340T | Missense Mutation (SNP) | VAF 211/471 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.394); catalogued as rs747818360; called by muse, mutect2, varscan2
- DNM1 | c.1877A>G p.Y626C | Missense Mutation (SNP) | VAF 162/356 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV57852990; called by muse, mutect2, varscan2
- DOCK10 | c.309G>T p.K103N | Missense Mutation (SNP) | VAF 113/240 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.112); catalogued as rs760214174; called by muse, mutect2, varscan2
- DOCK2 | c.3909G>T p.E1303D | Missense Mutation (SNP) | VAF 139/284 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV56952265; called by muse, mutect2, varscan2
- DOCK3 | c.4825C>T p.R1609W | Missense Mutation (SNP) | VAF 180/388 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372827222; called by muse, mutect2, varscan2
- DPEP2 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 156/363 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV99263265; called by muse, mutect2, varscan2
- DPF3 | c.803del p.G268Afs*4 | Frame Shift Del (DEL) | VAF 198/503 reads (39%) | catalogued as rs750670452, COSV63503637; called by mutect2, pindel, varscan2
- DRD5 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 240/545 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.151); catalogued as COSV58579350, COSV58580495; called by muse, varscan2
- DSCAML1 | c.451G>A p.A151T (on ENST00000321322; = p.A91T on NM_020693.4) | Missense Mutation (SNP) | VAF 33/446 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.893); catalogued as rs773114652, COSV58397545; called by muse, mutect2
- DST | c.18445C>T p.R6149W (on ENST00000361203 / NM_001374722.1; = p.R3846W on NM_015548.5) | Missense Mutation (SNP) | VAF 129/303 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55021142; called by muse, mutect2, varscan2
- EGR4 | c.79del p.E27Sfs*127 | Frame Shift Del (DEL) | VAF 257/676 reads (38%) | catalogued as rs1254850903; called by mutect2, pindel, varscan2
- EIF2AK3 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 142/320 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV57546764; called by muse, mutect2
- EIF3D | c.1483A>G p.I495V | Missense Mutation (SNP) | VAF 230/479 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.047); catalogued as rs750796856; called by muse, mutect2, varscan2
- EIF4G1 | c.3322G>A p.A1108T (on ENST00000346169 / NM_198241.3; = p.A913T on NM_004953.5) | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1412041818, COSV100072038; called by muse, mutect2, varscan2
- ENG | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 115/304 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781374732, CD111562, COSV100785288; called by muse, mutect2, varscan2
- ENTPD4 | c.800C>T p.A267V | Missense Mutation (SNP) | VAF 218/465 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs368158333; called by muse, mutect2, varscan2
- EP400 | c.3907G>A p.V1303I | Missense Mutation (SNP) | VAF 289/416 reads (69%) | SIFT tolerated (0.48); PolyPhen benign (0.154); catalogued as rs756769631, COSV57772559; called by muse, mutect2, varscan2
- EPN2 | c.1408dup p.T470Nfs*19 | Frame Shift Ins (INS) | VAF 88/202 reads (44%) | catalogued as rs756461692; called by mutect2, varscan2
- EPRS1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194185772, COSV65098335; called by muse, mutect2
- ERCC6 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as rs56397747, COSV63388105; called by muse, varscan2
- ERICH5 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 77/167 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs575526227, COSV59315550; called by muse, mutect2, varscan2
- ETV3L | c.689C>T p.A230V | Missense Mutation (SNP) | VAF 238/510 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as rs749240007; called by muse, mutect2, varscan2
- EXD2 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 252/488 reads (52%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs762841088; called by muse, varscan2
- FAIM2 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 118/365 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1338575908, COSV57741552; called by muse, mutect2, varscan2
- FAM160A2 | c.1667G>A p.R556H (on ENST00000449352 / NM_001098794.2; = p.R570H on NM_032127.4) | Missense Mutation (SNP) | VAF 81/456 reads (18%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.511); catalogued as rs776188632, COSV56414640; called by muse, mutect2, varscan2
- FAM186A | c.1512A>T p.K504N | Missense Mutation (SNP) | VAF 136/410 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as rs1375371440; called by muse, mutect2, varscan2
- FAM90A1 | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 215/696 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs751824794; called by muse, varscan2
- FAM9B | c.112del p.E38Kfs*33 | Frame Shift Del (DEL) | VAF 154/216 reads (71%) | catalogued as COSV59120493; called by mutect2, pindel, varscan2
- FAT2 | c.4615G>A p.V1539M | Missense Mutation (SNP) | VAF 67/350 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1163755925; called by muse, mutect2, varscan2
- FAT3 | c.7225dup p.R2409Pfs*12 | Frame Shift Ins (INS) | VAF 133/352 reads (38%) | catalogued as rs1246276508; called by mutect2, pindel, varscan2
- FBXL16 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 322/637 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs1015024619; called by muse, varscan2
- FCGRT | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 252/526 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs767515922; called by muse, mutect2, varscan2
- FERMT2 | c.455del p.K152Rfs*4 | Frame Shift Del (DEL) | VAF 144/332 reads (43%) | catalogued as rs766229731; called by mutect2, varscan2
- FGF4 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 126/250 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs750386794; called by muse, mutect2, varscan2
- FIZ1 | c.1166C>A p.A389E | Missense Mutation (SNP) | VAF 314/664 reads (47%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV55609374; called by mutect2, varscan2
- FLG | c.8249C>T p.S2750F | Missense Mutation (SNP) | VAF 145/670 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); catalogued as COSV100911591; called by muse, mutect2, varscan2
- FLNC | c.4651G>A p.A1551T | Missense Mutation (SNP) | VAF 268/561 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs565918031, CM1512373, COSV100367563; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLOT2 | c.1234G>A p.V412M | Missense Mutation (SNP) | VAF 196/410 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs201936801; called by muse, mutect2, varscan2
- FMO3 | c.611G>A p.S204N | Missense Mutation (SNP) | VAF 49/318 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV63008228; called by muse, mutect2, varscan2
- FN1 | c.2902T>A p.S968T | Missense Mutation (SNP) | VAF 236/507 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV60560883; called by muse, mutect2, varscan2
- FNIP1 | c.2773del p.I925Lfs*3 | Frame Shift Del (DEL) | VAF 124/327 reads (38%) | catalogued as COSV100330154; called by mutect2, pindel, varscan2
- FOXB1 | c.787A>G p.I263V | Missense Mutation (SNP) | VAF 451/891 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as COSV68526082; called by muse, mutect2, varscan2
- FOXN2 | c.60G>C p.K20N | Missense Mutation (SNP) | VAF 160/311 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.136); catalogued as COSV61319880; called by muse, mutect2, varscan2
- FPR1 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 253/491 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as rs764940294, COSV59050865, COSV59052341; called by muse, mutect2, varscan2
- FREM2 | c.686G>T p.R229L | Missense Mutation (SNP) | VAF 305/567 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1268329107; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 57/114 reads (50%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSHR | c.1711G>C p.A571P | Missense Mutation (SNP) | VAF 187/401 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58622879; called by muse, mutect2, varscan2
- FXR2 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 171/380 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747570442; called by muse, mutect2, varscan2
- GALNT13 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 52/158 reads (33%) | catalogued as COSV67221648; called by muse, mutect2, varscan2
- GBF1 | c.1150G>A p.V384M (on ENST00000369983 / NM_001377137.1; = p.V383M on NM_004193.3) | Missense Mutation (SNP) | VAF 112/270 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375568604; called by muse, mutect2, varscan2
- GBP6 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 272/532 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as rs1239638494; called by muse, mutect2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 501/1021 reads (49%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLYR1 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 284/584 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58926789; called by muse, mutect2, varscan2
- GNAS | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 301/651 reads (46%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.015); catalogued as rs368773762; called by muse, mutect2, varscan2
- GNB3 | c.348del p.L117Wfs*42 | Frame Shift Del (DEL) | VAF 430/818 reads (53%) | catalogued as rs1555123834; called by mutect2, pindel, varscan2
- GNE | c.1522C>T p.R508C (on ENST00000396594 / NM_001128227.3; = p.R477C on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/364 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs551854437, COSV64952240; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 110/252 reads (44%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GPM6B | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 122/152 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs150919148; called by muse, mutect2, varscan2
- GPRC6A | c.1355del p.N452Mfs*2 | Frame Shift Del (DEL) | VAF 55/184 reads (30%) | catalogued as rs1362947110; called by mutect2, pindel, varscan2
- GRID1 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 273/625 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs770555419, COSV60049348; called by muse, mutect2, varscan2
- GRM1 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 77/150 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs1376755373, COSV51218613; called by muse, mutect2, varscan2
- HAS1 | c.48C>A p.C16* | Nonsense Mutation (SNP) | VAF 222/492 reads (45%) | catalogued as rs775720322; called by muse, mutect2
- HCFC1 | c.3689C>T p.A1230V | Missense Mutation (SNP) | VAF 381/381 reads (100%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs782575778; called by muse, mutect2, varscan2
- HDAC6 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 110/323 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782393826, COSV61927334, COSV61930227; called by muse, mutect2, varscan2
- HDAC9 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1054512034, COSV101286646; called by muse, mutect2, varscan2
- HECTD1 | c.3781C>T p.R1261W | Missense Mutation (SNP) | VAF 139/261 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs761985708, COSV67945554; called by muse, mutect2, varscan2
- HECTD4 | c.12695C>T p.A4232V | Missense Mutation (SNP) | VAF 87/580 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV66400393; called by muse, mutect2, varscan2
- HECTD4 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 323/528 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101108412; called by muse, mutect2, varscan2
- HELLS | c.461del p.N154Ifs*29 | Frame Shift Del (DEL) | VAF 26/95 reads (27%) | catalogued as rs775038246; called by mutect2, varscan2
- HERC2 | c.10516G>A p.A3506T | Missense Mutation (SNP) | VAF 229/488 reads (47%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.99); catalogued as rs753148118; called by muse, mutect2, varscan2
- HGF | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 169/411 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55945952; called by muse, mutect2, varscan2
- HGS | c.2248del p.Q750Sfs*50 | Frame Shift Del (DEL) | VAF 227/564 reads (40%) | catalogued as rs748765403; called by mutect2, pindel, varscan2
- HK3 | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 278/583 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs763084624; called by muse, mutect2, varscan2
- HLA-B | c.19C>T p.R7* | Nonsense Mutation (SNP) | VAF 348/675 reads (52%) | catalogued as rs776780353, COSV69520663, COSV69521156; called by muse, mutect2, varscan2
- HMCN1 | c.11266A>G p.N3756D | Missense Mutation (SNP) | VAF 106/220 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as rs1169004163; called by muse, varscan2
- HMCN1 | c.12370C>T p.R4124C | Missense Mutation (SNP) | VAF 249/490 reads (51%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs760181577; called by muse, mutect2, varscan2
- HMCN1 | c.16792C>T p.R5598* | Nonsense Mutation (SNP) | VAF 190/400 reads (48%) | catalogued as rs193921043, COSV54900490; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HOXA3 | c.927del p.A310Pfs*66 | Frame Shift Del (DEL) | VAF 115/298 reads (39%) | catalogued as COSV100415778, COSV57828432; called by mutect2, pindel, varscan2
- HS3ST4 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 223/481 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs530100445; called by muse, mutect2, varscan2
- HSD11B1L | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 257/548 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780249226; called by muse, mutect2, varscan2
- HSPA2 | c.836C>T p.S279L | Missense Mutation (SNP) | VAF 310/579 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV55969700; called by muse, mutect2, varscan2
- HSPG2 | c.4673G>A p.G1558D | Missense Mutation (SNP) | VAF 185/373 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV101020405; called by muse, mutect2, varscan2
- HTR1A | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 237/471 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV60503596; called by muse, mutect2, varscan2
- IFIT2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 78/185 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.88); catalogued as rs1389691613, COSV51078771; called by muse, mutect2, varscan2
- IFT172 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 90/195 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as rs561676433, COSV99561700; called by muse, mutect2, varscan2
- IGF2R | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 192/421 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201251256, COSV100808065; called by muse, mutect2, varscan2
- IGFALS | c.1031C>T p.T344M | Missense Mutation (SNP) | VAF 242/497 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); catalogued as rs775129479; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INPP5J | c.1688C>T p.A563V (on ENST00000331075 / NM_001284285.2; = p.A195V on NM_001002837.2) | Missense Mutation (SNP) | VAF 215/470 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1474656992; called by muse, mutect2, varscan2
- IQSEC3 | c.2911G>A p.V971M (on ENST00000538872 / NM_001170738.2; = p.V668M on NM_015232.1) | Missense Mutation (SNP) | VAF 585/935 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs781933231; called by muse, mutect2, varscan2
- IRF2BPL | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 308/620 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as COSV53148986; called by muse, mutect2, varscan2
- IRGC | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 326/662 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775131068, COSV54985962; called by muse, mutect2, varscan2
- ISCA1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 258/580 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs772924113; called by muse, mutect2, varscan2
- ITGAM | c.3251C>T p.P1084L (on ENST00000648685 / NM_001145808.2; = p.P1083L on NM_000632.4) | Missense Mutation (SNP) | VAF 169/399 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs779963762, COSV99792276; called by muse, mutect2, varscan2
- ITGB4 | c.3079C>T p.R1027C | Missense Mutation (SNP) | VAF 261/545 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs761988708; called by muse, mutect2, varscan2
- ITIH2 | c.2383G>A p.D795N | Missense Mutation (SNP) | VAF 118/238 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs541401394; called by muse, mutect2, varscan2
- IWS1 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 196/423 reads (46%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs368651104; called by muse, mutect2, varscan2
- JAKMIP3 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 141/269 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs199726287, COSV53829249; called by muse, mutect2, varscan2
- KAT14 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 161/340 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs368262295; called by muse, mutect2, varscan2
- KAT6B | c.5836C>T p.R1946C | Missense Mutation (SNP) | VAF 208/464 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs747683895, COSV54755013; called by muse, varscan2
- KCNA3 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 305/639 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100871326; called by muse, mutect2, varscan2
- KCND2 | c.13del p.V5Wfs*41 | Frame Shift Del (DEL) | VAF 181/423 reads (43%) | catalogued as COSV58583583, COSV58589056; called by mutect2, pindel, varscan2
- KCNH8 | c.2352del p.N785Tfs*10 | Frame Shift Del (DEL) | VAF 159/394 reads (40%) | catalogued as rs760381227; called by mutect2, pindel, varscan2
- KCNMA1 | c.1642G>A p.A548T | Missense Mutation (SNP) | VAF 176/341 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as rs974940310, COSV99697522; called by muse, mutect2, varscan2
- KCNN3 | c.335del p.P112Lfs*64 | Frame Shift Del (DEL) | VAF 311/610 reads (51%) | catalogued as rs753256170; called by mutect2, varscan2
- KCNV2 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 94/646 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs370129493; called by muse, mutect2, varscan2
- KCNV2 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 351/712 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs750543416; called by muse, mutect2, varscan2
- KDM4B | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 267/511 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as rs746418499; called by muse, mutect2, varscan2
- KDM4B | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 198/405 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs774551918; called by muse, varscan2
- KIAA0100 | c.4286G>A p.R1429H | Missense Mutation (SNP) | VAF 128/260 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs1442125591, COSV101197332; called by muse, mutect2, varscan2
- KIAA0895 | c.433C>T p.R145C (on ENST00000297063 / NM_001100425.2; = p.R94C on NM_015314.3) | Missense Mutation (SNP) | VAF 144/359 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.431); catalogued as rs201511349, COSV51709631; called by muse, mutect2, varscan2
- KIAA1210 | c.2263G>T p.G755* | Nonsense Mutation (SNP) | VAF 183/185 reads (99%) | catalogued as COSV68176251; called by muse, mutect2, varscan2
- KIAA1549 | c.4519C>T p.R1507* | Nonsense Mutation (SNP) | VAF 189/379 reads (50%) | catalogued as rs759848796, COSV54317872; called by muse, mutect2, varscan2
- KIDINS220 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 147/303 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99876431; called by muse, mutect2, varscan2
- KIF15 | c.2816G>A p.R939H | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs747160107, COSV58163245; called by muse, mutect2, varscan2
- KIF7 | c.2425C>T p.R809W | Missense Mutation (SNP) | VAF 235/465 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs367734857; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF7 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 125/324 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV101067583; called by muse, mutect2, varscan2
- KLHL22 | c.1676G>A p.R559H | Missense Mutation (SNP) | VAF 228/478 reads (48%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.947); catalogued as rs758290191, COSV99839432; called by muse, varscan2
- KLHL9 | c.1762C>T p.R588* | Nonsense Mutation (SNP) | VAF 134/377 reads (36%) | catalogued as COSV62921599; called by muse, mutect2, varscan2
- KMT2B | c.3057del p.G1020Afs*4 | Frame Shift Del (DEL) | VAF 146/390 reads (37%) | catalogued as rs868041281; called by mutect2, pindel, varscan2
- KMT2B | c.5264C>A p.P1755H | Missense Mutation (SNP) | VAF 147/325 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55861847; called by muse, mutect2, varscan2
- KNDC1 | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 318/635 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs753247446; called by muse, mutect2, varscan2
- KRTAP5-3 | c.644A>G p.Q215R | Missense Mutation (SNP) | VAF 311/691 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as rs776467860; called by muse, mutect2, varscan2
- LAMA3 | c.3704dup p.N1235Kfs*6 | Frame Shift Ins (INS) | VAF 105/268 reads (39%) | catalogued as rs751004787; called by mutect2, pindel, varscan2
- LATS2 | c.2554del p.D852Tfs*3 | Frame Shift Del (DEL) | VAF 214/534 reads (40%) | catalogued as COSV66875447; called by mutect2, pindel, varscan2
- LEKR1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as rs775370423, COSV62962980; called by muse, mutect2, varscan2
- LGR6 | c.2730del p.R911Gfs*8 (on ENST00000367278 / NM_001017403.1; = p.R859Gfs*8 on NM_021636.3) | Frame Shift Del (DEL) | VAF 246/627 reads (39%) | catalogued as COSV55163759; called by mutect2, pindel, varscan2
- LILRB5 | c.1762del p.L588Wfs*34 (on ENST00000449561 / NM_001081442.3; = p.L587Wfs*34 on NM_006840.5) | Frame Shift Del (DEL) | VAF 177/398 reads (44%) | catalogued as rs775329343; called by mutect2, varscan2
- LLGL2 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 227/463 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs146449794; called by muse, mutect2, varscan2
- LMTK3 | c.1961G>A p.S654N | Missense Mutation (SNP) | VAF 418/786 reads (53%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as rs970188262; called by muse, mutect2, varscan2
- LNX1 | c.670dup p.I224Nfs*29 (on ENST00000263925 / NM_001126328.3; = p.I128Nfs*29 on NM_032622.2) | Frame Shift Ins (INS) | VAF 160/349 reads (46%) | catalogued as rs771430050; called by mutect2, varscan2
- LRFN1 | c.2212del p.A738Lfs*144 | Frame Shift Del (DEL) | VAF 380/866 reads (44%) | catalogued as COSV50489346; called by mutect2, pindel, varscan2
- LRP12 | c.1352G>A p.C451Y | Missense Mutation (SNP) | VAF 185/377 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV52629483; called by muse, mutect2, varscan2
- LRP2 | c.6728G>A p.R2243Q | Missense Mutation (SNP) | VAF 226/530 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.223); catalogued as rs775126007, COSV55543487; called by muse, mutect2
- LRRC24 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 277/563 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs539958520; called by muse, mutect2, varscan2
- LRRC53 | c.1486C>G p.L496V | Missense Mutation (SNP) | VAF 110/236 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); catalogued as COSV53945466; called by muse, mutect2, varscan2
- LUZP4 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 114/265 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.114); catalogued as rs782527922; called by muse, varscan2
- MAB21L1 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 254/523 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59800229; called by muse, mutect2, varscan2
- MAEL | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 192/408 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as rs745572154; called by muse, mutect2, varscan2
- MAGEE2 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 261/262 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs781070212, COSV100973158; called by muse, mutect2, varscan2
- MAGI2 | c.2675C>T p.T892I | Missense Mutation (SNP) | VAF 212/431 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV100832495; called by muse, mutect2, varscan2
- MAK | c.1787del p.N596Tfs*2 | Frame Shift Del (DEL) | VAF 219/510 reads (43%) | catalogued as COSV57564550, COSV57566119; called by mutect2, pindel, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 52/117 reads (44%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MAST4 | c.6152C>T p.A2051V (on ENST00000403625 / NM_001164664.2; = p.A1862V on NM_015183.3) | Missense Mutation (SNP) | VAF 52/614 reads (8%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs776957434, COSV55134496; called by muse, mutect2
- MDH1B | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 176/406 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs948551312, COSV65588753; called by muse, mutect2, varscan2
- MED4 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1398194412; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 362/831 reads (44%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MEGF8 | c.7156G>A p.A2386T (on ENST00000251268 / NM_001271938.2; = p.A2319T on NM_001410.3) | Missense Mutation (SNP) | VAF 175/337 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1425341413, COSV52087811; called by muse, mutect2, varscan2
- METTL24 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 271/570 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1306927874; called by muse, mutect2, varscan2
- MEX3A | c.200dup p.G68Rfs*89 | Frame Shift Ins (INS) | VAF 58/138 reads (42%) | catalogued as rs773021630; called by mutect2, varscan2
- MFRP | c.79G>T p.A27S (on ENST00000449574; = p.A409S on NM_031433.4) | Missense Mutation (SNP) | VAF 124/296 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64129412; called by muse, mutect2, varscan2
- MFSD6 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 212/484 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as rs554501896, COSV55622918; called by muse, mutect2, varscan2
- MGA | c.4151del p.G1384Vfs*12 | Frame Shift Del (DEL) | VAF 205/550 reads (37%) | catalogued as COSV54961299, COSV99579909; called by mutect2, pindel, varscan2
- MICAL1 | c.2690C>T p.A897V | Missense Mutation (SNP) | VAF 102/227 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs374654125; called by muse, mutect2, varscan2
- MKNK2 | c.663del p.V222* | Frame Shift Del (DEL) | VAF 304/726 reads (42%) | catalogued as rs866318050; called by mutect2, pindel, varscan2
- MKS1 | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 110/264 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs749668169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP7 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 110/229 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs200159966, COSV52773292; called by muse, mutect2, varscan2
- MOCOS | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 226/462 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs149743314; called by muse, mutect2
- MOCOS | c.931G>T p.V311L | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT tolerated (0.85); PolyPhen benign (0.04); catalogued as rs749438838; called by muse, mutect2, varscan2
- MOCS1 | c.721del p.L241Wfs*6 | Frame Shift Del (DEL) | VAF 163/429 reads (38%) | catalogued as CD111818; called by mutect2, pindel, varscan2
- MON1A | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 309/592 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as rs764383245, COSV56562174; called by muse, mutect2, varscan2
- MORF4L2 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 313/313 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.305); catalogued as rs756143552; called by muse, mutect2, varscan2
- MOV10L1 | c.2384G>A p.R795Q | Missense Mutation (SNP) | VAF 188/378 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779178382, COSV53179337; called by muse, mutect2, varscan2
- MPO | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 248/506 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751670403; called by muse, mutect2, varscan2
- MRGPRD | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 251/491 reads (51%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs777395337, COSV58424185; called by muse, mutect2, varscan2
- MRO | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs770852600; called by muse, mutect2, varscan2
- MS4A12 | c.453G>T p.K151N | Missense Mutation (SNP) | VAF 117/258 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); catalogued as COSV99188519; called by muse, mutect2, varscan2
- MS4A6A | c.553_554del p.T185Sfs*29 | Frame Shift Del (DEL) | VAF 91/199 reads (46%) | catalogued as COSV60616210; called by mutect2, pindel, varscan2
- MSC | c.417del p.D140Tfs*37 | Frame Shift Del (DEL) | VAF 285/647 reads (44%) | catalogued as COSV57696108; called by mutect2, pindel, varscan2
- MUC5B | c.1898C>T p.S633L | Missense Mutation (SNP) | VAF 257/542 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs757830332; called by muse, mutect2, varscan2
- MYBPC3 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 224/493 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs397516051, CM1410972; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH11 | c.3560C>T p.T1187M | Missense Mutation (SNP) | VAF 230/519 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.86); catalogued as rs552818350; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH13 | c.5341G>A p.A1781T | Missense Mutation (SNP) | VAF 54/450 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs377063691; called by muse, mutect2, varscan2
- MYL3 | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 238/487 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs752549068, COSV52767666; ClinVar: uncertain significance; called by muse, varscan2
- MYLK3 | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 41/542 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1329249080; called by muse, mutect2
- MYO15A | c.1444C>T p.R482* | Nonsense Mutation (SNP) | VAF 260/518 reads (50%) | catalogued as rs867369805, COSV52765541; called by muse, mutect2, varscan2
- MYO18B | c.6772C>T p.R2258W | Missense Mutation (SNP) | VAF 168/433 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368571524, COSV59151680; called by muse, mutect2, varscan2
- MYO5A | c.2950C>T p.R984W | Missense Mutation (SNP) | VAF 43/447 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs373825708; called by muse, mutect2
- MYO5A | c.2398G>A p.V800M | Missense Mutation (SNP) | VAF 171/342 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.217); catalogued as rs1292830989, COSV62561748; called by muse, mutect2, varscan2
- MYOM3 | c.2425C>T p.R809W | Missense Mutation (SNP) | VAF 142/288 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs753189960; called by mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 98/228 reads (43%) | catalogued as rs763929397; called by mutect2, varscan2
- NAT10 | c.672G>A p.P224= | Splice Region (SNP) | VAF 138/293 reads (47%) | catalogued as rs780017579, COSV99139960; called by muse, mutect2, varscan2
- NEBL | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 102/289 reads (35%) | catalogued as rs370153729, COSV65800323; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEO1 | c.2197C>A p.L733I | Missense Mutation (SNP) | VAF 100/198 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99981406; called by muse, mutect2, varscan2
- NEXMIF | c.3731G>T p.G1244V | Missense Mutation (SNP) | VAF 310/310 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.072); catalogued as COSV50207576; called by muse, mutect2, varscan2
- NFATC4 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 305/702 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755617374; called by muse, mutect2, varscan2
- NIPAL4 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 273/531 reads (51%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs367993555, COSV99978565; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 122/310 reads (39%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NLRC5 | c.1346del p.P449Lfs*17 | Frame Shift Del (DEL) | VAF 70/470 reads (15%) | catalogued as rs772651939; called by mutect2, pindel, varscan2
- NLRP8 | c.2593C>T p.Q865* | Nonsense Mutation (SNP) | VAF 141/306 reads (46%) | catalogued as rs1039222958; called by muse, mutect2, varscan2
- NNAT | c.190G>A p.A64T (on ENST00000649309 / NM_001322802.2; = p.S65= on NM_005386.4) | Missense Mutation (SNP) | VAF 297/599 reads (50%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.085); catalogued as rs755637405; called by muse, mutect2, varscan2
- NOS2 | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 190/436 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201545022; called by muse, mutect2, varscan2
- NOTCH1 | c.2176G>A p.V726I | Missense Mutation (SNP) | VAF 228/443 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs746313097, COSV104374373; called by muse, mutect2, varscan2
- NOVA1 | c.135C>T p.G45= | Splice Region (SNP) | VAF 168/338 reads (50%) | catalogued as COSV57483086; called by muse, mutect2, varscan2
- NPHP3 | c.1118G>T p.S373I | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as CS163029; called by muse, mutect2, varscan2
- NPR3 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 313/634 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.66); catalogued as rs1305279076; called by muse, mutect2, varscan2
- NR1D2 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 138/271 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.297); catalogued as rs746002238, COSV100437295; called by muse, mutect2, varscan2
- NR3C2 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 240/494 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs371233416; called by muse, mutect2, varscan2
- NSMCE3 | c.12del p.K4Nfs*84 | Frame Shift Del (DEL) | VAF 221/574 reads (39%) | catalogued as rs1338647631; called by mutect2, pindel, varscan2
- NUP42 | c.212dup p.S72Qfs*13 | Frame Shift Ins (INS) | VAF 114/286 reads (40%) | catalogued as rs758695627; called by mutect2, varscan2
- OBSCN | c.18781dup p.A6261Gfs*121 | Frame Shift Ins (INS) | VAF 244/514 reads (47%) | catalogued as rs757515520; called by mutect2, varscan2
- ODF2 | c.1282G>A p.A428T (on ENST00000434106 / NM_153433.2; = p.A404T on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.646); catalogued as rs1374445698; called by muse, mutect2
- OGDH | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 198/391 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56048752; called by muse, mutect2, varscan2
- OLFM3 | c.1394A>G p.N465S (on ENST00000338858 / NM_001288821.1; = p.N445S on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1230620005; called by muse, mutect2, varscan2
- OR11A1 | c.432del p.L145Wfs*12 | Frame Shift Del (DEL) | VAF 372/884 reads (42%) | catalogued as rs1473295719; called by mutect2, pindel, varscan2
- OR2L13 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 160/327 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as rs747401128, COSV63552858; called by muse, mutect2, varscan2
- OR4N2 | chr14:19828372 del A | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | catalogued as rs1233785490; called by mutect2, pindel, varscan2
- OR9Q2 | c.566G>A p.C189Y | Missense Mutation (SNP) | VAF 210/408 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100285504; called by muse, mutect2, varscan2
- OSBPL10 | c.656C>T p.T219M | Missense Mutation (SNP) | VAF 230/489 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); catalogued as rs142587699; called by muse, mutect2, varscan2
- OTOGL | c.6893C>A p.P2298Q (on ENST00000547103; = p.P2289Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100086518; called by muse, mutect2, varscan2
- PAAF1 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 180/368 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.212); catalogued as rs991612076; called by muse, mutect2, varscan2
- PAMR1 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 116/234 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs369548670; called by muse, mutect2, varscan2
- PANX2 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 191/397 reads (48%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs746980968; called by muse, mutect2, varscan2
- PCDH17 | c.1555G>A p.V519M | Missense Mutation (SNP) | VAF 215/442 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as COSV64972583; called by muse, mutect2, varscan2
- PCDHA2 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 127/247 reads (51%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV65371421; called by muse, mutect2, varscan2
- PCDHB3 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 352/414 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV50564230; called by mutect2, varscan2
- PCLO | c.11030G>A p.R3677H | Missense Mutation (SNP) | VAF 146/313 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs139066156, COSV61616280; called by muse, mutect2, varscan2
- PCLO | c.3770del p.P1257Qfs*61 | Frame Shift Del (DEL) | VAF 168/408 reads (41%) | catalogued as COSV61627976; called by mutect2, pindel, varscan2
- PCM1 | c.3865G>A p.A1289T | Missense Mutation (SNP) | VAF 153/296 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760725769; called by muse, mutect2, varscan2
- PCMT1 | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 336/714 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs936805166; called by muse, varscan2
- PCNX3 | c.5618C>T p.P1873L | Missense Mutation (SNP) | VAF 22/630 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1253637616; called by muse, mutect2
- PCSK1N | c.90del p.A31Rfs*7 | Frame Shift Del (DEL) | VAF 258/356 reads (72%) | catalogued as rs1569507015; called by mutect2, pindel, varscan2
- PDE4B | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778940030, COSV58489182; called by muse, mutect2, varscan2
- PDHA1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs1460386114, COSV100870253; called by muse, mutect2, varscan2
- PDIA4 | c.1756G>A p.A586T (on ENST00000286091 / NM_001371244.1; = p.A585T on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 235/491 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs752610120, COSV53727283; called by muse, mutect2, varscan2
- PFKL | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 286/606 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs369155274; called by muse, mutect2, varscan2
- PFKL | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs887684613, COSV104410733; called by muse, mutect2, varscan2
- PGLYRP2 | c.1172C>T p.A391V | Missense Mutation (SNP) | VAF 212/393 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.237); catalogued as COSV52994878; called by muse, mutect2, varscan2
- PHKG2 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 298/608 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs532137455, COSV60312800; called by muse, mutect2, varscan2
- PIGB | c.840del p.F280Lfs*12 | Frame Shift Del (DEL) | VAF 66/164 reads (40%) | catalogued as rs756552559; called by mutect2, varscan2
- PIGW | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 183/419 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs763678894; called by muse, mutect2, varscan2
- PKHD1L1 | c.8678C>T p.A2893V | Missense Mutation (SNP) | VAF 90/194 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs1261165409; called by muse, mutect2, varscan2
- PLAGL2 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 260/503 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs768724030, COSV55788937; called by muse, varscan2
- PLB1 | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 168/388 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755710557; called by muse, mutect2, varscan2
- PLCG2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 126/277 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs780140339; called by muse, mutect2, varscan2
- PLD5 | c.308dup p.N103Kfs*5 (on ENST00000442594; = p.N41Kfs*5 on NM_001195811.1 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 107/224 reads (48%) | catalogued as rs1558485246; called by mutect2, varscan2
- PLEC | c.8021A>G p.Q2674R (on ENST00000322810 / NM_201380.4; = p.Q2564R on NM_000445.5) | Missense Mutation (SNP) | VAF 328/652 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.45); catalogued as rs781861513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEK2 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 194/375 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs1411781769, COSV53604329; called by muse, mutect2, varscan2
- PLEKHA7 | c.955G>A p.G319R | Missense Mutation (SNP) | VAF 280/539 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs770945767; called by muse, mutect2, varscan2
- PLK3 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 176/473 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.017); catalogued as rs201492855, COSV59499068; called by muse, mutect2, varscan2
- PLXNC1 | c.3382C>T p.R1128C | Missense Mutation (SNP) | VAF 205/688 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138337903; called by muse, mutect2, varscan2
- PMPCA | c.1505C>T p.T502M | Missense Mutation (SNP) | VAF 290/550 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs1490474361, COSV65510914; called by muse, mutect2, varscan2
- PNPLA6 | c.2215G>A p.V739M (on ENST00000414982 / NM_001166111.2; = p.V691M on NM_006702.5) | Missense Mutation (SNP) | VAF 165/332 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as COSV55378662; called by muse, mutect2, varscan2
- POTEF | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 102/794 reads (13%) | catalogued as COSV62541836; called by pindel, varscan2
- POTEI | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 50/476 reads (11%) | catalogued as rs775721804; called by mutect2, pindel, varscan2
- PPIL2 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 243/556 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs767679035; called by muse, mutect2, varscan2
- PRDM15 | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 179/315 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs927132818; called by muse, mutect2, varscan2
- PRELP | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 297/585 reads (51%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.745); catalogued as rs148190160; called by muse, varscan2
- PRM3 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 294/581 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1394852130; called by muse, mutect2, varscan2
- PTPN3 | c.1848del p.E617Kfs*21 | Frame Shift Del (DEL) | VAF 173/456 reads (38%) | catalogued as COSV99355862; called by mutect2, pindel, varscan2
- PTPRS | c.5426C>T p.P1809L | Missense Mutation (SNP) | VAF 120/251 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1440460687, COSV53623375; called by muse, mutect2, varscan2
- PXDN | c.2621G>A p.R874H | Missense Mutation (SNP) | VAF 232/441 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs753691649; called by muse, mutect2, varscan2
- PYDC1 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 246/674 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57252103; called by muse, mutect2, varscan2
- RALYL | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 150/329 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759722399, COSV101569085; called by muse, mutect2, varscan2
- RALYL | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 126/290 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs747588101, COSV101569255; called by muse, mutect2, varscan2
- RARRES1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 362/770 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866994982; called by muse, mutect2
- RASGRP1 | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 72/433 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs372045194; called by muse, mutect2, varscan2
- RBM47 | c.666G>T p.W222C | Missense Mutation (SNP) | VAF 308/642 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99921198; called by muse, mutect2
- RC3H1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 191/401 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749182810, COSV51225780; called by muse, mutect2, varscan2
- REELD1 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 209/391 reads (53%) | SIFT tolerated (0.25); PolyPhen benign (0.24); catalogued as rs1160049459; called by muse, mutect2, varscan2
- RELA | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 174/345 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58015044; called by muse, varscan2
- REXO5 | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 102/243 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs752694478; called by muse, mutect2, varscan2
- RFC2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 244/500 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1554721623; called by muse, mutect2, varscan2
- RFX6 | c.2707G>A p.G903R | Missense Mutation (SNP) | VAF 154/344 reads (45%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.154); catalogued as rs762777811; called by muse, mutect2, varscan2
- RIMS2 | c.3983G>A p.R1328H | Missense Mutation (SNP) | VAF 39/438 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs775941559, COSV51702799; called by muse, mutect2
- RNF113B | c.232G>T p.G78C | Missense Mutation (SNP) | VAF 296/594 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV99940393; called by muse, mutect2, varscan2
- RNF157 | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 163/321 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs1033262530, COSV99486802; called by muse, mutect2, varscan2
- RNF166 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 176/359 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as rs747470452; called by muse, mutect2, varscan2
- RNF43 | c.2002del p.R668Gfs*32 | Frame Shift Del (DEL) | VAF 230/660 reads (35%) | catalogued as COSV68459021; called by pindel, varscan2
- ROGDI | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 133/443 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV59021546; called by muse, mutect2, varscan2
- RP1L1 | c.851del p.P284Rfs*26 | Frame Shift Del (DEL) | VAF 104/690 reads (15%) | catalogued as rs757272743; called by pindel, varscan2
- RPS10-NUDT3 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 125/268 reads (47%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.947); catalogued as COSV100402582; called by muse, mutect2, varscan2
- RRP1 | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 142/287 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs771516121, COSV68544769; called by muse, mutect2, varscan2
- RSBN1L | c.1598T>C p.M533T | Missense Mutation (SNP) | VAF 167/314 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as rs370568123; called by muse, mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 88/176 reads (50%) | catalogued as rs756606313; called by mutect2, varscan2
- RUSC1 | c.2467C>T p.R823W (on ENST00000368352 / NM_001105203.2; = p.R354W on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 169/489 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs905865423; called by muse, mutect2, varscan2
- RYR3 | c.1443G>A p.M481I | Missense Mutation (SNP) | VAF 96/223 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as rs1407017492; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 228/573 reads (40%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SBF2 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99814342; called by muse, mutect2, varscan2
- SBNO2 | c.2266del p.R756Afs*25 | Frame Shift Del (DEL) | VAF 193/474 reads (41%) | catalogued as COSV62319212; called by mutect2, pindel, varscan2
- SCART1 | c.1923del p.R642Gfs*20 | Frame Shift Del (DEL) | VAF 314/784 reads (40%) | catalogued as rs1285387406; called by mutect2, pindel, varscan2
- SCN7A | c.233del p.N78Ifs*4 | Frame Shift Del (DEL) | VAF 68/130 reads (52%) | catalogued as rs764500272; called by mutect2, varscan2
- SEC16A | c.6197del p.P2066Qfs*76 | Frame Shift Del (DEL) | VAF 63/704 reads (9%) | catalogued as COSV99256980; called by mutect2, pindel
- SEC63 | c.47_49del p.F16del | In Frame Del (DEL) | VAF 210/471 reads (45%) | catalogued as rs752984272; called by pindel, varscan2
- SEL1L2 | c.58A>G p.T20A | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV53151921; called by muse, mutect2, varscan2
- SEMA3E | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 154/336 reads (46%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.57); catalogued as rs369848880, COSV57078944; called by muse, varscan2
- SEMA6D | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 118/265 reads (45%) | catalogued as rs1265629390; called by muse, mutect2, varscan2
- SENP1 | c.1227del p.G410Vfs*4 | Frame Shift Del (DEL) | VAF 100/314 reads (32%) | catalogued as rs750651342; called by mutect2, varscan2
- SENP6 | c.1908A>T p.E636D | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100519598; called by muse, mutect2, varscan2
- SEPTIN2 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 162/327 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs918257127, COSV63633300; called by muse, mutect2, varscan2
- SERPINI1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 100/165 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs777674608, COSV99854765; called by muse, mutect2, varscan2
- SETD1A | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 353/703 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.47); catalogued as rs771940541, COSV99352959; called by muse, mutect2, varscan2
- SEZ6L2 | c.2708C>T p.T903M (on ENST00000308713 / NM_001114099.3; = p.T846M on NM_012410.4) | Missense Mutation (SNP) | VAF 222/436 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs144165415; called by muse, mutect2, varscan2
- SGCE | c.464C>A p.T155K (on ENST00000647096; = p.T119K on NM_003919.3) | Missense Mutation (SNP) | VAF 126/260 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs766764222; called by muse, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 108/217 reads (50%) | catalogued as rs1469942319; called by mutect2, varscan2
- SLC16A11 | c.547G>A p.A183T (on ENST00000308009; = p.A159T on NM_153357.3) | Missense Mutation (SNP) | VAF 345/640 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs760337883; called by muse, mutect2, varscan2
- SLC1A2 | c.1151G>A p.R384H | Missense Mutation (SNP) | VAF 219/451 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374504230; called by muse, mutect2, varscan2
- SLC2A10 | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 180/391 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1238866581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC38A7 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 32/580 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as rs1224800278; called by muse, mutect2
- SLC48A1 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 36/876 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs775333312; called by muse, mutect2
- SLC4A4 | c.1015G>A p.E339K (on ENST00000264485 / NM_001098484.3; = p.E295K on NM_003759.4) | Missense Mutation (SNP) | VAF 111/270 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52639757; called by muse, mutect2, varscan2
- SLC52A3 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 238/488 reads (49%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs111912321, COSV54077751, COSV99447662; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A20 | c.749_751del p.F250del | In Frame Del (DEL) | VAF 176/407 reads (43%) | catalogued as rs776438424; called by pindel, varscan2
- SLC7A2 | c.958G>A p.D320N (on ENST00000494857 / NM_001370338.1; = p.D360N on NM_003046.6) | Missense Mutation (SNP) | VAF 254/510 reads (50%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.721); catalogued as rs866647549, COSV50249976; called by muse, mutect2, varscan2
- SLF2 | c.2713A>T p.I905F | Missense Mutation (SNP) | VAF 127/282 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV53275583; called by muse, mutect2, varscan2
- SMARCA4 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 229/509 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.044); catalogued as rs1305138096, COSV100759442; called by muse, mutect2, varscan2
- SMARCA4 | c.3614G>A p.C1205Y | Missense Mutation (SNP) | VAF 213/460 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs112043656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCD2 | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 140/286 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1130104; called by muse, mutect2, varscan2
- SMYD1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 255/502 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs771710072, COSV70226020; called by muse, mutect2, varscan2
- SOGA3 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 295/612 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767905851; called by muse, mutect2, varscan2
- SPNS2 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 214/495 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs369109561; called by muse, mutect2, varscan2
- SPRED3 | c.130del p.R44Afs*23 | Frame Shift Del (DEL) | VAF 144/396 reads (36%) | catalogued as rs777573843; called by pindel, varscan2
- SPSB4 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 146/754 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.487); catalogued as rs747734915; called by muse, mutect2, varscan2
- SRCAP | c.3935T>C p.V1312A | Missense Mutation (SNP) | VAF 228/460 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs1366072563; called by muse, mutect2, varscan2
- SRCAP | c.4291G>A p.V1431I | Missense Mutation (SNP) | VAF 325/707 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.039); catalogued as rs774989117; called by muse, mutect2, varscan2
- ST6GAL2 | c.574G>A p.G192S | Missense Mutation (SNP) | VAF 339/644 reads (53%) | PolyPhen benign (0.005); catalogued as rs143354621; called by muse, mutect2, varscan2
- ST8SIA4 | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 100/214 reads (47%) | PolyPhen probably damaging (0.964); catalogued as COSV99185150; called by muse, mutect2, varscan2
- STAG1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs757393709, COSV52600654; called by muse, mutect2, varscan2
- STAT6 | c.2023G>A p.A675T | Missense Mutation (SNP) | VAF 268/406 reads (66%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs761861730; called by muse, varscan2
- STIMATE | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 227/454 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as rs775080125, COSV100753615, COSV61891505; called by muse, mutect2, varscan2
- STK10 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 211/394 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs757807481, COSV51575397; called by muse, mutect2, varscan2
- STK32B | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 151/289 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs754708470, COSV51483857; called by muse, mutect2, varscan2
- STX17 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs941324900; called by muse, mutect2, varscan2
- SUPT6H | c.4696G>A p.A1566T | Missense Mutation (SNP) | VAF 208/504 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.225); catalogued as rs1229320091; called by muse, mutect2, varscan2
- SYBU | c.1795G>A p.V599M (on ENST00000276646 / NM_001099754.2; = p.V598M on NM_017786.6) | Missense Mutation (SNP) | VAF 273/551 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV52615934; called by muse, mutect2, varscan2
- SYNE1 | c.19322C>T p.S6441F (on ENST00000367255 / NM_182961.4; = p.S6370F on NM_033071.3) | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV55088333; called by muse, mutect2, varscan2
- SYT12 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 129/307 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764600530; called by muse, mutect2, varscan2
- SZT2 | c.8660G>A p.R2887Q (on ENST00000634258 / NM_001365999.1; = p.R2830Q on NM_015284.4) | Missense Mutation (SNP) | VAF 245/451 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as rs141085666; ClinVar: uncertain significance; called by muse, mutect2
- SZT2 | c.9628C>T p.R3210C (on ENST00000634258 / NM_001365999.1; = p.R3153C on NM_015284.4) | Missense Mutation (SNP) | VAF 252/515 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762786100, COSV65095024; called by muse, mutect2, varscan2
- TBC1D31 | c.1893del p.H632Tfs*8 | Frame Shift Del (DEL) | VAF 68/138 reads (49%) | catalogued as rs768246273; called by mutect2, varscan2
- TBX19 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 252/526 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs199644548, COSV100892370; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBX4 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 346/726 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs1284363848; called by muse, mutect2, varscan2
- TCAF2 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 98/534 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.009); catalogued as rs757355702; called by muse, mutect2, varscan2
- TCF20 | c.5826del p.L1943Cfs*118 | Frame Shift Del (DEL) | VAF 226/497 reads (45%) | catalogued as rs756457255; called by mutect2, varscan2
- TDRD15 | c.863C>T p.T288M | Missense Mutation (SNP) | VAF 64/261 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as rs1267840741; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 176/348 reads (51%) | catalogued as rs763321097; called by mutect2, varscan2
- TEAD4 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 357/1050 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs151141907; called by muse, mutect2, varscan2
- TEKT4 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 318/688 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs548168000; called by muse, mutect2, varscan2
- TEKT4 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 313/615 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs373542007, COSV99726808; called by muse, mutect2, varscan2
- TENT5B | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 227/464 reads (49%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1241068049, COSV100006756; called by muse, mutect2, varscan2
- TFE3 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 288/288 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV59946315; called by muse, mutect2, varscan2
- TGM5 | c.1100G>A p.S367N (on ENST00000220420 / NM_201631.4; = p.S285N on NM_004245.4) | Missense Mutation (SNP) | VAF 195/394 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1170356220; called by muse, mutect2, varscan2
- THAP4 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 273/510 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs769268345; called by muse, varscan2
- THSD7A | c.1679C>A p.P560H | Missense Mutation (SNP) | VAF 174/347 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101448616; called by muse, mutect2, varscan2
- TLR9 | c.2246C>T p.A749V | Missense Mutation (SNP) | VAF 109/468 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs762617367; called by muse, varscan2
- TMEM109 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 125/268 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs753654818, COSV50003100; called by muse, mutect2, varscan2
- TMEM121B | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 301/664 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV58898471; called by muse, mutect2, varscan2
- TMEM129 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 269/533 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.413); catalogued as rs756918029, COSV57559528; called by muse, mutect2, varscan2
- TMEM151A | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 323/687 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV59173123; called by muse, mutect2, varscan2
- TMEM187 | c.553T>C p.Y185H | Missense Mutation (SNP) | VAF 425/425 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1220960938; called by muse, mutect2, varscan2
- TMEM200C | c.1024A>G p.T342A | Missense Mutation (SNP) | VAF 325/672 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1039892357; called by muse, mutect2, varscan2
- TMEM229A | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 119/707 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1237580426; called by muse, mutect2, varscan2
- TMEM259 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 355/721 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773104611; called by muse, mutect2
- TMIE | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 162/326 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375322709, COSV104398501; called by muse, mutect2, varscan2
- TNFRSF6B | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 278/592 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as rs1166317805; called by muse, mutect2, varscan2
- TNFRSF9 | c.345del p.G116Vfs*33 | Frame Shift Del (DEL) | VAF 124/253 reads (49%) | catalogued as rs752649731; called by mutect2, pindel, varscan2
- TNFSF11 | c.877G>A p.V293I | Missense Mutation (SNP) | VAF 153/309 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.848); catalogued as COSV53478996; called by muse, mutect2, varscan2
- TNXB | c.10838C>T p.A3613V (on ENST00000647633; = p.A3366V on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/462 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs772853952, COSV64481735; called by muse, mutect2, varscan2
- TPBGL | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 319/610 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs1252247129; called by muse, mutect2, varscan2
- TPM3 | c.567C>T p.S189= (on ENST00000368530 / NM_001364682.1; = p.S152= on NM_153649.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 138/293 reads (47%) | catalogued as COSV55137586; called by muse, mutect2, varscan2
- TRAF3 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 134/298 reads (45%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs746483559; called by muse, varscan2
- TRAM1L1 | c.436C>A p.L146M | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as COSV100162328; called by muse, mutect2, varscan2
- TRAPPC8 | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 105/238 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as rs759441223, COSV51971019; called by muse, mutect2, varscan2
- TRIM66 | c.3272G>A p.R1091Q | Missense Mutation (SNP) | VAF 168/365 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs764764835; called by muse, mutect2, varscan2
- TRPM5 | c.773del p.G258Afs*9 | Frame Shift Del (DEL) | VAF 315/713 reads (44%) | catalogued as rs1462581231; called by mutect2, pindel, varscan2
- TSHZ3 | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 205/450 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as rs200286730, COSV53668629; called by muse, mutect2, varscan2
- TSKS | c.1748del p.P583Qfs*? | Frame Shift Del (DEL) | VAF 168/441 reads (38%) | catalogued as rs749002253, COSV55877613; called by mutect2, pindel, varscan2
- TSPAN17 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 190/420 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as rs983868841; called by muse, mutect2, varscan2
- TSPEAR | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 156/371 reads (42%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as COSV100555255; called by muse, mutect2, varscan2
- TTC14 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 107/237 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs150222211; called by muse, mutect2, varscan2
- TTC28 | c.3731G>A p.G1244D | Missense Mutation (SNP) | VAF 124/265 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as rs966488098; called by muse, mutect2, varscan2
- TTC3 | c.4692del p.E1565Kfs*6 | Frame Shift Del (DEL) | VAF 84/164 reads (51%) | catalogued as rs778730652; called by mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 70/148 reads (47%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.58655G>A p.R19552H (on ENST00000591111; = p.R12128H on NM_003319.4) | Missense Mutation (SNP) | VAF 65/310 reads (21%) | PolyPhen probably damaging (0.998); catalogued as rs372267046; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- TTN | c.28964G>A p.R9655Q (on ENST00000591111; = p.R8728Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/331 reads (39%) | PolyPhen possibly damaging (0.905); catalogued as rs752814410, COSV60141316; called by muse, mutect2, varscan2
- TTN | c.12695C>T p.A4232V (on ENST00000591111; = p.A4186V on NM_003319.4) | Missense Mutation (SNP) | VAF 22/305 reads (7%) | catalogued as rs1560895836; called by muse, mutect2
- TTN | c.1964C>T p.A655V (on ENST00000591111; = p.A609V on NM_003319.4) | Missense Mutation (SNP) | VAF 95/196 reads (48%) | PolyPhen benign (0.197); catalogued as rs763912778; called by muse, mutect2, varscan2
- TUB | c.493G>A p.A165T (on ENST00000299506 / NM_177972.3; = p.A220T on NM_003320.4) | Missense Mutation (SNP) | VAF 207/456 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.049); catalogued as rs775955177; called by muse, mutect2, varscan2
- TUBA3C | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 73/804 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as rs544706766, COSV67139776; called by muse, mutect2
- TXNDC5 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 262/576 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs762345665, COSV65730285, COSV65730975; called by muse, mutect2, varscan2
- UBR4 | c.2276G>A p.R759H | Missense Mutation (SNP) | VAF 169/368 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs774960335; called by muse, mutect2, varscan2
- UGGT1 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 118/258 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs773049954, COSV52137385; called by muse, mutect2, varscan2
- UNC45A | c.1466G>A p.S489N | Missense Mutation (SNP) | VAF 132/266 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV101265643; called by muse, mutect2, varscan2
- UNC80 | c.7810C>T p.R2604* | Nonsense Mutation (SNP) | VAF 155/289 reads (54%) | catalogued as rs751900819, COSV55891885; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 111/226 reads (49%) | catalogued as rs767420916; called by mutect2, varscan2
- UPK3B | c.775G>A p.G259R (on ENST00000257632; = p.P230= on NM_001347684.2) | Missense Mutation (SNP) | VAF 280/581 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs771497466; called by muse, mutect2, varscan2
- UQCRFS1 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 82/379 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as rs377626806; called by muse, varscan2
- USP34 | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 43/472 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1385588612, COSV68398675; called by muse, mutect2
- USP36 | c.1853C>T p.S618L | Missense Mutation (SNP) | VAF 291/587 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as rs543707885; called by muse, mutect2, varscan2
- VAV3 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 194/484 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs964672810; called by muse, mutect2, varscan2
- VPS37D | c.712del p.L238Cfs*2 | Frame Shift Del (DEL) | VAF 30/174 reads (17%) | catalogued as rs1554609756; called by mutect2, varscan2
- VWA8 | c.1872C>A p.V624= | Splice Region (SNP) | VAF 69/152 reads (45%) | catalogued as COSV99865172; called by muse, mutect2, varscan2
- WNK2 | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 215/417 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1173298714, COSV52930435; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 180/559 reads (32%) | catalogued as rs771899177; called by pindel, varscan2
- WWC1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 147/288 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as rs545162323; called by muse, mutect2, varscan2
- XKR3 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 152/349 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.154); catalogued as rs563205767; called by muse, mutect2, varscan2
- YBX3 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 506/784 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.689); catalogued as rs1347313092, COSV54385350; called by muse, mutect2, varscan2
- ZBED5 | c.712del p.I238* | Frame Shift Del (DEL) | VAF 160/363 reads (44%) | catalogued as COSV69721336; called by mutect2, pindel, varscan2
- ZBTB7C | c.960dup p.P321Afs*141 | Frame Shift Ins (INS) | VAF 224/468 reads (48%) | catalogued as rs751294936; called by mutect2, varscan2
- ZDHHC11B | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 182/653 reads (28%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.347); catalogued as rs542419224; called by muse, mutect2, varscan2
- ZFAT | c.2572A>G p.M858V | Missense Mutation (SNP) | VAF 124/241 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs1023027461; called by muse, mutect2, varscan2
- ZFHX4 | c.2570C>A p.A857E | Missense Mutation (SNP) | VAF 131/280 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as rs752326078, COSV50496728; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1417C>T p.R473W | Missense Mutation (SNP) | VAF 202/424 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100363067; called by muse, mutect2, varscan2
- ZMIZ1 | c.2683G>A p.G895S | Missense Mutation (SNP) | VAF 105/242 reads (43%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.019); catalogued as COSV57900638; called by muse, mutect2, varscan2
- ZMYM1 | c.1516dup p.T506Nfs*9 | Frame Shift Ins (INS) | VAF 113/226 reads (50%) | catalogued as rs772297962; called by mutect2, varscan2
- ZNF121 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 93/171 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); catalogued as rs776653821; called by muse, varscan2
- ZNF121 | c.1106T>C p.I369T | Missense Mutation (SNP) | VAF 86/192 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as rs1306303276; called by muse, varscan2
- ZNF202 | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 229/456 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs370787823; called by muse, mutect2, varscan2
- ZNF292 | c.6145del p.S2049Vfs*11 | Frame Shift Del (DEL) | VAF 86/194 reads (44%) | catalogued as rs764995318; called by mutect2, varscan2
- ZNF318 | c.6011C>T p.T2004I | Missense Mutation (SNP) | VAF 197/405 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs760013388; called by muse, mutect2, varscan2
- ZNF341 | c.2431G>A p.A811T (on ENST00000375200 / NM_001282935.1; = p.A804T on NM_032819.4) | Missense Mutation (SNP) | VAF 333/716 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.01); catalogued as rs145551003; called by muse, mutect2, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 270/694 reads (39%) | catalogued as rs780189754; called by mutect2, pindel, varscan2
- ZNF516 | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 234/490 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs559349577; called by muse, mutect2, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 189/196 reads (96%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF529 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 25/382 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs766699853, COSV61900106; called by muse, mutect2
- ZNF562 | c.493G>A p.V165M (on ENST00000453372 / NM_001130032.2; = p.V93M on NM_017656.4) | Missense Mutation (SNP) | VAF 159/309 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.473); catalogued as rs987811921; called by muse, mutect2, varscan2
- ZNF564 | c.132A>G p.G44= | Splice Region (SNP) | VAF 72/165 reads (44%) | catalogued as rs1024922724, COSV100213076, COSV100213353, COSV59434102; called by muse, mutect2, varscan2
- ZNF653 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 251/538 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1167066255, COSV99542067; called by muse, mutect2, varscan2
- ZNF672 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 327/668 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs1392178911; called by muse, mutect2, varscan2
- ZNF687 | c.2924G>A p.R975H | Missense Mutation (SNP) | VAF 88/450 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs780745156; called by muse, mutect2, varscan2
- ZNF703 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 364/761 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1485814106; called by muse, mutect2, varscan2
- ZNF703 | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 264/696 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as rs1218308120; called by muse, mutect2, varscan2
- ZNF782 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 203/412 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs367983236; called by muse, mutect2, varscan2
- ZNF845 | c.2184C>A p.F728L | Missense Mutation (SNP) | VAF 99/179 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV72004684; called by muse, mutect2, varscan2
- ZSWIM3 | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 184/410 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757437589, COSV54848008; called by muse, mutect2, varscan2
- ZYG11B | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 206/427 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs377337861; called by muse, varscan2
- A3GALT2 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 222/412 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA13 | c.9681+7_9681+8del p.X3227_splice | Splice Site (DEL) | VAF 77/209 reads (37%) | called by pindel, varscan2
- ABCA2 | c.7009G>A p.A2337T (on ENST00000614293; = p.A2307T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 140/320 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- ABCD2 | c.592A>G p.N198D | Missense Mutation (SNP) | VAF 374/577 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ABHD10 | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 174/382 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AC005551.1 | c.413del p.P138Hfs*9 | Frame Shift Del (DEL) | VAF 115/267 reads (43%) | called by mutect2, pindel, varscan2
- AC073111.3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 247/488 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADAMTS20 | c.4414G>T p.V1472F | Missense Mutation (SNP) | VAF 105/313 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- ADCY8 | c.1172C>G p.T391S | Missense Mutation (SNP) | VAF 162/317 reads (51%) | SIFT tolerated (0.77); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADGRB3 | c.2458G>T p.V820L | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AFF3 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 239/503 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFG3L2 | c.255del p.A86Lfs*99 | Frame Shift Del (DEL) | VAF 61/180 reads (34%) | called by mutect2, pindel, varscan2
- AGRN | c.4849del p.L1617Wfs*32 | Frame Shift Del (DEL) | VAF 248/626 reads (40%) | called by mutect2, pindel, varscan2
- AHCTF1 | c.1134G>T p.R378S (on ENST00000366508; = p.R352S on NM_015446.5) | Missense Mutation (SNP) | VAF 168/409 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AHNAK2 | c.15167del p.G5056Vfs*30 | Frame Shift Del (DEL) | VAF 160/415 reads (39%) | called by mutect2, pindel, varscan2
- AHR | c.140T>C p.L47S | Missense Mutation (SNP) | VAF 209/382 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AIM2 | c.1006-11_1018delinsCTCCATCCAGGTTATTAAGGCC p.X336_splice | Splice Site (DEL) | VAF 105/415 reads (25%) | called by pindel, varscan2*
- AKAP13 | c.5284A>C p.S1762R (on ENST00000394518 / NM_007200.5; = p.S1766R on NM_006738.6) | Missense Mutation (SNP) | VAF 103/184 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, varscan2
- ALDH2 | c.1111C>A p.L371I | Missense Mutation (SNP) | VAF 44/640 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2
- ALPP | c.1425G>T p.Q475H | Missense Mutation (SNP) | VAF 370/982 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.237); called by muse, varscan2
- ANAPC2 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 248/510 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ANKRD26 | c.691_693del p.S231del | In Frame Del (DEL) | VAF 32/92 reads (35%) | called by pindel, varscan2
- ANKRD33B | c.496+1del | Frame Shift Del (DEL) | VAF 117/291 reads (40%) | called by mutect2, pindel, varscan2
- ANKRD34A | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 91/575 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- ANKRD34A | c.502del p.V168Wfs*85 | Frame Shift Del (DEL) | VAF 256/631 reads (41%) | called by mutect2, pindel, varscan2
- ANLN | c.2596T>G p.F866V | Missense Mutation (SNP) | VAF 73/179 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ANO5 | c.118C>T p.L40F | Missense Mutation (SNP) | VAF 107/243 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- AP2A1 | c.2551del p.Q851Rfs*5 | Frame Shift Del (DEL) | VAF 167/428 reads (39%) | called by mutect2, pindel, varscan2
- AP2S1 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 187/424 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARAP1 | c.4348G>A p.V1450I (on ENST00000393609 / NM_001040118.2; = p.V1205I on NM_015242.4) | Missense Mutation (SNP) | VAF 191/395 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ARC | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 346/713 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ARHGEF11 | c.1462C>T p.R488* | Nonsense Mutation (SNP) | VAF 186/382 reads (49%) | called by muse, varscan2
- ARX | c.745del p.E249Rfs*76 | Frame Shift Del (DEL) | VAF 316/445 reads (71%) | called by mutect2, pindel, varscan2
- ASTN2 | c.2469G>T p.E823D (on ENST00000313400 / NM_001365069.1; = p.E772D on NM_014010.5) | Missense Mutation (SNP) | VAF 182/366 reads (50%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- ATG5 | c.704del p.K235Rfs*4 | Frame Shift Del (DEL) | VAF 120/300 reads (40%) | called by mutect2, pindel, varscan2
- ATN1 | c.1993_1995del p.F665del | In Frame Del (DEL) | VAF 312/1063 reads (29%) | called by mutect2, pindel, varscan2
- ATP10D | c.1058del p.F353Sfs*24 | Frame Shift Del (DEL) | VAF 139/331 reads (42%) | called by mutect2, pindel, varscan2
- ATP2B4 | c.3575C>T p.P1192L | Missense Mutation (SNP) | VAF 181/375 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATRIP | c.1033del p.L345Cfs*31 | Frame Shift Del (DEL) | VAF 128/345 reads (37%) | called by mutect2, pindel, varscan2
- AZI2 | c.969G>C p.E323D | Missense Mutation (SNP) | VAF 127/253 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- B9D2 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 202/436 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- BCOR | c.3621dup p.Q1208Tfs*8 (on ENST00000378444 / NM_001123385.2; = p.Q1174Tfs*8 on NM_017745.6) | Frame Shift Ins (INS) | VAF 236/339 reads (70%) | called by mutect2, pindel, varscan2
- BFSP1 | c.1101del p.K368Rfs*10 | Frame Shift Del (DEL) | VAF 168/432 reads (39%) | called by mutect2, pindel, varscan2
- BMP8B | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 61/424 reads (14%) | called by muse, varscan2
- BMPR1A | c.345dup p.A116Sfs*16 | Frame Shift Ins (INS) | VAF 102/244 reads (42%) | called by mutect2, pindel, varscan2
- BTBD2 | c.821C>T p.T274I | Missense Mutation (SNP) | VAF 36/544 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- BTBD3 | c.73A>G p.R25G | Missense Mutation (SNP) | VAF 146/315 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTN2A2 | c.1436C>A p.P479H | Missense Mutation (SNP) | VAF 251/501 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BTN3A3 | c.744G>T p.W248C | Missense Mutation (SNP) | VAF 123/262 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C15orf39 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 310/654 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C4orf54 | c.1331C>T p.T444M | Missense Mutation (SNP) | VAF 259/561 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CABLES2 | c.149dup p.F51Lfs*106 | Frame Shift Ins (INS) | VAF 53/297 reads (18%) | called by mutect2, pindel, varscan2
- CACNA1A | c.4454G>T p.G1485V | Missense Mutation (SNP) | VAF 182/385 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CACNA1H | c.5300G>T p.G1767V | Missense Mutation (SNP) | VAF 215/429 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1I | c.5090G>A p.S1697N | Missense Mutation (SNP) | VAF 191/411 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CALHM1 | c.1027T>G p.F343V | Missense Mutation (SNP) | VAF 41/527 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- CAMTA1 | c.953G>A p.S318N | Missense Mutation (SNP) | VAF 33/446 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.02); called by muse, mutect2
- CAPN2 | c.1352del p.N451Tfs*4 | Frame Shift Del (DEL) | VAF 163/381 reads (43%) | called by mutect2, pindel, varscan2
- CAPRIN1 | c.71C>A p.S24Y | Missense Mutation (SNP) | VAF 384/794 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CC2D1B | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 167/378 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CCDC138 | c.852del p.K284Nfs*3 | Frame Shift Del (DEL) | VAF 15/124 reads (12%) | called by pindel, varscan2
- CCDC146 | c.2444del p.N815Mfs*6 | Frame Shift Del (DEL) | VAF 70/188 reads (37%) | called by mutect2, pindel, varscan2
- CCN4 | c.196dup p.V66Gfs*9 | Frame Shift Ins (INS) | VAF 308/793 reads (39%) | called by mutect2, pindel, varscan2
- CCNF | c.1586A>G p.E529G | Missense Mutation (SNP) | VAF 79/426 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CCNK | c.1381dup p.L461Pfs*123 | Frame Shift Ins (INS) | VAF 204/498 reads (41%) | called by mutect2, pindel, varscan2
- CD19 | c.1176del p.S393Pfs*76 | Frame Shift Del (DEL) | VAF 72/517 reads (14%) | called by mutect2, pindel, varscan2
- CD79A | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 135/267 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CDC42BPA | c.2509T>C p.Y837H | Missense Mutation (SNP) | VAF 97/203 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CDH10 | c.1920del p.E641Sfs*3 | Frame Shift Del (DEL) | VAF 104/271 reads (38%) | called by mutect2, pindel, varscan2
- CDK11A | c.582G>T p.E194D (on ENST00000378633 / NM_001313896.2; = p.E204D on NM_024011.4) | Missense Mutation (SNP) | VAF 276/1128 reads (24%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.121); called by muse, varscan2
- CDT1 | c.853del p.Q285Sfs*33 | Frame Shift Del (DEL) | VAF 254/603 reads (42%) | called by mutect2, pindel, varscan2
- CEL | c.2190del p.T731Rfs*30 (on ENST00000673714; = p.T728Rfs*30 on NM_001807.6) | Frame Shift Del (DEL) | VAF 196/507 reads (39%) | called by pindel, varscan2
- CELSR3 | c.1445C>A p.A482D | Missense Mutation (SNP) | VAF 144/724 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CEP104 | c.2539del p.L847Cfs*17 | Frame Shift Del (DEL) | VAF 135/350 reads (39%) | called by mutect2, pindel, varscan2
- CEP128 | c.1595T>G p.L532R | Missense Mutation (SNP) | VAF 97/176 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP295 | c.7733C>T p.A2578V | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- CEP89 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 164/362 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, varscan2
- CEP95 | c.624del p.A209Pfs*2 | Frame Shift Del (DEL) | VAF 99/261 reads (38%) | called by mutect2, pindel, varscan2
- CES4A | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 218/489 reads (45%) | called by muse, mutect2, varscan2
- CFAP251 | c.1982-1G>A p.X661_splice | Splice Site (SNP) | VAF 52/322 reads (16%) | called by muse, mutect2, varscan2
- CFAP47 | c.1410G>A p.V470= | Splice Region (SNP) | VAF 92/92 reads (100%) | called by muse, mutect2, varscan2
- CGNL1 | c.1643A>G p.Q548R | Missense Mutation (SNP) | VAF 141/297 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- CHAF1A | c.320A>G p.E107G | Missense Mutation (SNP) | VAF 169/344 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CHD4 | c.2796del p.K932Nfs*28 (on ENST00000357008 / NM_001363606.2; = p.K945Nfs*28 on NM_001273.5) | Frame Shift Del (DEL) | VAF 215/826 reads (26%) | called by mutect2, pindel, varscan2
- CIC | c.1304G>A p.G435D | Missense Mutation (SNP) | VAF 349/768 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CILP | c.3505G>A p.V1169M | Missense Mutation (SNP) | VAF 53/580 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- CLEC18B | c.669del p.L224Sfs*11 | Frame Shift Del (DEL) | VAF 140/518 reads (27%) | called by mutect2, pindel, varscan2
- CNOT3 | c.1373del p.P458Lfs*45 | Frame Shift Del (DEL) | VAF 242/595 reads (41%) | called by mutect2, pindel, varscan2
- CNTNAP3 | c.2447A>G p.D816G | Missense Mutation (SNP) | VAF 161/340 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- COL6A5 | c.4591G>T p.G1531* | Nonsense Mutation (SNP) | VAF 95/194 reads (49%) | called by muse, mutect2, varscan2
- COPA | c.512del p.N171Tfs*11 | Frame Shift Del (DEL) | VAF 101/220 reads (46%) | called by mutect2, varscan2
- CORIN | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 121/258 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CPSF6 | c.112T>C p.S38P | Missense Mutation (SNP) | VAF 93/337 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- CPVL | c.1251del p.V418Ffs*24 | Frame Shift Del (DEL) | VAF 175/438 reads (40%) | called by mutect2, varscan2
- CRYL1 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 265/552 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSMD1 | c.7901A>C p.K2634T (on ENST00000520002; = p.K2633T on NM_033225.6) | Missense Mutation (SNP) | VAF 135/264 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CSMD1 | c.481T>A p.F161I | Missense Mutation (SNP) | VAF 201/346 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CSMD3 | c.8797T>A p.C2933S (on ENST00000297405 / NM_001363185.1; = p.C2764S on NM_052900.3) | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CSPG5 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 337/701 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CST6 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 313/635 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CTSD | c.1097G>A p.C366Y | Missense Mutation (SNP) | VAF 185/400 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CTXN2 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 129/259 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CUBN | c.4643T>C p.V1548A | Missense Mutation (SNP) | VAF 135/273 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- CUTC | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CYLC1 | c.1256A>G p.Q419R | Missense Mutation (SNP) | VAF 120/121 reads (99%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CYP3A43 | c.1461A>C p.K487N (on ENST00000354829 / NM_057095.3; = p.K488N on NM_022820.5) | Missense Mutation (SNP) | VAF 70/147 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CYP8B1 | c.1420dup p.H474Pfs*3 | Frame Shift Ins (INS) | VAF 205/510 reads (40%) | called by mutect2, pindel, varscan2
- CYTH3 | c.1200del p.K400Nfs*6 (on ENST00000396741; = p.K399Nfs*6 on NM_004227.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 130/330 reads (39%) | called by mutect2, pindel, varscan2
- DAAM2 | c.1574del p.P525Lfs*11 | Frame Shift Del (DEL) | VAF 214/479 reads (45%) | called by mutect2, pindel, varscan2
- DACH1 | c.1964del p.L655* (on ENST00000619232 / NM_001366712.1; = p.L401* on NM_004392.6) | Frame Shift Del (DEL) | VAF 174/423 reads (41%) | called by mutect2, pindel, varscan2
- DACT1 | c.1593dup p.V532Rfs*86 | Frame Shift Ins (INS) | VAF 196/478 reads (41%) | called by mutect2, pindel, varscan2
- DACT3 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 217/442 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- DAG1 | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 239/500 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCAF4L2 | c.242C>G p.T81S | Missense Mutation (SNP) | VAF 195/380 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DDIT4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 85/374 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DEDD2 | c.419C>T p.A140V | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DGUOK | c.74G>T p.G25V | Missense Mutation (SNP) | VAF 280/586 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- DIAPH3 | c.986G>A p.G329D (on ENST00000400324 / NM_001042517.2; = p.G66D on NM_030932.3) | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DLGAP3 | c.1130del p.G377Vfs*91 | Frame Shift Del (DEL) | VAF 145/344 reads (42%) | called by mutect2, varscan2
- DMXL2 | c.5763dup p.D1922Rfs*4 | Frame Shift Ins (INS) | VAF 133/299 reads (44%) | called by mutect2, varscan2
- DNAAF1 | c.113del p.G38Afs*51 | Frame Shift Del (DEL) | VAF 52/545 reads (10%) | called by mutect2, pindel
- DNAH10 | c.3704A>T p.D1235V (on ENST00000409039; = p.D1174V on NM_207437.3) | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC8 | c.6_8del p.A3del | In Frame Del (DEL) | VAF 192/429 reads (45%) | called by pindel, varscan2
- DNHD1 | c.13334A>G p.Q4445R | Missense Mutation (SNP) | VAF 89/472 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- DNM3 | c.1340C>A p.A447E | Missense Mutation (SNP) | VAF 98/195 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DOT1L | c.199del p.S67Afs*30 | Frame Shift Del (DEL) | VAF 112/288 reads (39%) | called by mutect2, pindel, varscan2
- DPP8 | c.53C>T p.A18V (on ENST00000341861 / NM_001320875.2; = p.A2V on NM_017743.6) | Missense Mutation (SNP) | VAF 115/266 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- DRD3 | c.111C>A p.C37* | Nonsense Mutation (SNP) | VAF 137/467 reads (29%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.3122dup p.M1041Ifs*6 | Frame Shift Ins (INS) | VAF 131/355 reads (37%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.12139C>T p.P4047S | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- ECEL1 | c.673C>T p.R225* | Nonsense Mutation (SNP) | VAF 323/605 reads (53%) | called by muse, mutect2, varscan2
- EFR3B | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 62/420 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- EGFR | c.707G>A p.C236Y | Missense Mutation (SNP) | VAF 29/586 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELOVL5 | c.428A>G p.H143R | Missense Mutation (SNP) | VAF 254/467 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMID1 | c.686G>A p.G229D | Missense Mutation (SNP) | VAF 208/433 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EMILIN1 | c.2921T>G p.I974S | Missense Mutation (SNP) | VAF 160/865 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ENPP4 | c.334del p.W112Gfs*10 | Frame Shift Del (DEL) | VAF 160/381 reads (42%) | called by mutect2, pindel, varscan2
- ENPP5 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 139/316 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ERG | c.786dup p.R263Qfs*29 (on ENST00000398919 / NM_001243428.1; = p.R239Qfs*29 on NM_004449.4) | Frame Shift Ins (INS) | VAF 216/526 reads (41%) | called by mutect2, pindel, varscan2
- ESR1 | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 183/390 reads (47%) | called by muse, mutect2, varscan2
- EVI2A | c.5C>A p.P2H | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.19); called by muse, varscan2
- EXOC3 | c.1791G>T p.E597D | Missense Mutation (SNP) | VAF 200/416 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- EXT2 | c.956_957del p.V319Gfs*35 (on ENST00000343631; = p.V352Gfs*35 on NM_000401.3) | Frame Shift Del (DEL) | VAF 154/406 reads (38%) | called by pindel, varscan2
- EXTL1 | c.5A>C p.Q2P | Missense Mutation (SNP) | VAF 152/321 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- F2RL2 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 92/204 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- FAM151A | c.571A>T p.T191S | Missense Mutation (SNP) | VAF 135/246 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- FAM160A2 | c.1895del p.P632Lfs*30 (on ENST00000449352 / NM_001098794.2; = p.P646Lfs*30 on NM_032127.4) | Frame Shift Del (DEL) | VAF 160/404 reads (40%) | called by mutect2, pindel, varscan2
- FAM177A1 | c.236T>C p.L79P (on ENST00000382406 / NM_001289022.2; = p.L102P on NM_173607.5) | Missense Mutation (SNP) | VAF 136/274 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM186A | c.3156del p.S1053Pfs*55 | Frame Shift Del (DEL) | VAF 202/638 reads (32%) | called by mutect2, varscan2
- FAM214A | c.418T>A p.F140I | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, varscan2
- FAT4 | c.14752A>G p.T4918A | Missense Mutation (SNP) | VAF 179/425 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXO11 | c.2553C>T p.Y851= (on ENST00000403359 / NM_001190274.2; = p.Y767= on NM_025133.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 54/121 reads (45%) | called by muse, mutect2, varscan2
- FBXO21 | c.505del p.I169Ffs*11 | Frame Shift Del (DEL) | VAF 162/259 reads (63%) | called by mutect2, varscan2
- FBXO46 | c.1271del p.P424Rfs*34 | Frame Shift Del (DEL) | VAF 353/852 reads (41%) | called by mutect2, pindel, varscan2
- FBXW2 | c.1337A>G p.H446R | Missense Mutation (SNP) | VAF 189/360 reads (53%) | SIFT tolerated (0.3); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- FBXW7 | c.2001del p.S668Vfs*39 (on ENST00000281708 / NM_001349798.2; = p.S588Vfs*39 on NM_018315.5) | Frame Shift Del (DEL) | VAF 259/645 reads (40%) | called by mutect2, pindel, varscan2
- FCRL1 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 163/327 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- FLAD1 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 174/409 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FLNC | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 42/219 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- FOXI3 | c.1187G>A p.S396N | Missense Mutation (SNP) | VAF 255/497 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FREM1 | c.1398del p.L470Sfs*56 | Frame Shift Del (DEL) | VAF 42/243 reads (17%) | called by mutect2, pindel, varscan2
- FRMD1 | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 266/547 reads (49%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSCB | c.753del p.V252Wfs*6 | Frame Shift Del (DEL) | VAF 147/379 reads (39%) | called by mutect2, pindel, varscan2
- FUT4 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 402/898 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- FXR1 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 70/182 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- GABBR1 | c.1189G>A p.A397T | Missense Mutation (SNP) | VAF 275/614 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
857 further variants in this file (365 protein-altering or splice-affecting, 412 silent, 80 other) are not listed here.
